CCDI case PBBMJK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/87481776-1846-46af-b7ce-6597e367d6a9

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (467 days).

Biospecimens (4 samples)
- Sample 0DCWB5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCWBA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DCWBG, 0DCY0H (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
